Somatic mutation profile of tumor specimen TCGA-G3-AAV7-01A (aliquot TCGA-G3-AAV7-01A-11D-A382-10) from TCGA case TCGA-G3-AAV7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 39.0 years (14,229 days).
Specimen TCGA-G3-AAV7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf29c6bb-3d7a-49cc-8119-0eab434b9b06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV7-10A (Blood Derived Normal), aliquot TCGA-G3-AAV7-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55957c00-7a12-42b0-ae8c-f68357e53550

The open-access MAF lists 89 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 22, Nonsense Mutation 6, Frame Shift Del 4, Intron 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.607+1G>A p.X203_splice | Splice Site (SNP) | VAF 16/37 reads (43%) | hotspot (GDC flag); catalogued as rs587776789, CD084205, CS951522, CS961676, CS961677, COSV57294293, COSV57310480; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.785del p.G262Vfs*83 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as rs879253905, COSV52677105, COSV52952688; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AJUBA | c.693T>G p.Y231* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99400843; called by muse, mutect2, varscan2
- AKNAD1 | c.298A>C p.N100H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100645374; called by muse, mutect2, varscan2
- ANKRD29 | c.696A>T p.K232N | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99409056; called by muse, mutect2, varscan2
- ANKS1B | c.3617A>G p.E1206G (on ENST00000547776 / NM_152788.4; = p.E372G on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV100227355, COSV59120054; called by muse, mutect2, varscan2
- ARMC2 | c.1036A>G p.R346G | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933484; called by muse, mutect2, varscan2
- BIRC6 | c.7187A>G p.D2396G | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV101427954; called by muse, mutect2, varscan2
- C3orf20 | c.479T>C p.M160T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs758945154, COSV99513498; called by muse, mutect2, varscan2
- CCDC180 | c.3262C>G p.Q1088E | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100826600; called by muse, mutect2, varscan2
- CCNDBP1 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99543368; called by muse, mutect2, varscan2
- CEP97 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV100511580; called by muse, mutect2, varscan2
- CHUK | c.2149C>A p.L717I | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.861); catalogued as COSV100957012; called by muse, mutect2, varscan2
- CREB3L4 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV99676644; called by muse, mutect2, varscan2
- CUBN | c.7412C>G p.P2471R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1467349581, COSV100912196, COSV64724016; called by muse, mutect2, varscan2
- CUBN | c.1684A>G p.N562D | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as COSV100912197; called by muse, mutect2, varscan2
- DSEL | c.2321T>C p.I774T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100025350; called by muse, mutect2, varscan2
- EPB41L3 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1234278432, COSV100548287; called by muse, mutect2
- FHL5 | c.355A>G p.K119E | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV100459207; called by muse, mutect2, varscan2
- FLG2 | c.5566G>T p.G1856* | Nonsense Mutation (SNP) | VAF 38/227 reads (17%) | catalogued as COSV101165644; called by muse, mutect2, varscan2
- FRMPD2 | c.3126T>A p.C1042* | Nonsense Mutation (SNP) | VAF 143/357 reads (40%) | catalogued as rs1246780858, COSV100563587; called by muse, mutect2, varscan2
- FSIP2 | c.16138A>G p.M5380V | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100554295; called by muse, mutect2, varscan2
- GLIS1 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV100389552; called by muse, mutect2, varscan2
- GP1BA | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); catalogued as rs1476897044, COSV99850908; called by muse, mutect2, varscan2
- GRID1 | c.2405A>G p.Q802R | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.142); catalogued as COSV100022390; called by muse, mutect2, varscan2
- H3C3 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 51/191 reads (27%) | catalogued as rs1018182182, COSV100778253; called by muse, mutect2, varscan2
- HEATR3 | c.1505A>G p.Q502R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99589796; called by muse, mutect2, varscan2
- HYAL1 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 106/345 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99807492; called by muse, mutect2, varscan2
- IPP | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs767412927, COSV100739408; called by muse, mutect2, varscan2
- LRIT1 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100928025; called by muse, mutect2, varscan2
- LRRC37A2 | c.4810A>T p.I1604L | Missense Mutation (SNP) | VAF 161/571 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs762616867, COSV100238650; called by muse, mutect2, varscan2
- MPC2 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99607487; called by muse, mutect2, varscan2
- MYRIP | c.1845C>A p.N615K | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV100218484; called by muse, mutect2, varscan2
- NCAN | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99386707; called by muse, mutect2, varscan2
- NES | c.4580G>A p.G1527D | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100957776; called by muse, mutect2, varscan2
- OFD1 | c.1925C>G p.A642G | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV100406754; called by muse, mutect2, varscan2
- OXGR1 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100036901; called by muse, mutect2, varscan2
- PAEP | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs373981009; called by muse, mutect2, varscan2
- PCNX3 | c.6042G>T p.W2014C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs748832469, COSV100856087, COSV63140984; called by muse, mutect2, varscan2
- PEAR1 | c.272G>C p.C91S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99440778; called by muse, mutect2
- RFWD3 | c.1976A>G p.N659S | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV100736183; called by muse, mutect2, varscan2
- SCYL3 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 190/475 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100884266; called by muse, mutect2, varscan2
- SELENOP | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101539861; called by muse, mutect2, varscan2
- SGO1 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.192); catalogued as COSV99768190; called by muse, mutect2, varscan2
- SIGLECL1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs149546733; called by muse, mutect2, varscan2
- SLC16A9 | c.1397T>A p.F466Y | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV101264337, COSV68100293; called by muse, mutect2, varscan2
- SNTG2 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV100421680; called by muse, mutect2, varscan2
- SYMPK | c.1866G>T p.W622C | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs1180489120, COSV55615824; called by muse, varscan2
- SYMPK | c.1865G>T p.W622L | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV99841449; called by muse, varscan2
- TBC1D22A | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs761726540, COSV61437924; called by muse, mutect2, varscan2
- TDRD5 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs1295276272, COSV99675686; called by muse, mutect2, varscan2
- TLN1 | c.6356A>G p.K2119R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV100147407; called by muse, mutect2, varscan2
- TMC8 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100129956; called by muse, mutect2, varscan2
- TMEM121B | c.1723G>C p.A575P | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100082912; called by muse, mutect2
- TRAK1 | c.1065G>C p.M355I (on ENST00000327628 / NM_001349247.2; = p.M297I on NM_014965.5) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100409809; called by muse, mutect2, varscan2
- TRPC1 | c.487G>A p.V163I (on ENST00000476941 / NM_001251845.2; = p.V129I on NM_003304.4) | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.989); catalogued as COSV99858347; called by muse, mutect2, varscan2
- TSC2 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs45517233, CM091029, COSV99552998; ClinVar: not provided; called by muse, mutect2, varscan2
- TTC13 | c.2300G>C p.R767P | Missense Mutation (SNP) | VAF 100/1014 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752321035, COSV100792867; called by muse, mutect2
- WEE2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV101285130; called by muse, mutect2, varscan2
- YEATS2 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 62/200 reads (31%) | catalogued as COSV100527543; called by muse, mutect2, varscan2
- ZNF687 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs746046631, COSV100133950, COSV60678468; called by muse, mutect2, varscan2
- AGL | c.4293_4294del p.L1432Rfs*3 | Frame Shift Del (DEL) | VAF 123/436 reads (28%) | called by mutect2, pindel, varscan2
- AXIN1 | c.915dup p.V306Cfs*45 | Frame Shift Ins (INS) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
- IARS1 | c.2875_2882del p.A959* | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, varscan2
- MANEA | c.265_281delinsACCTC p.S89_D94delinsTS | In Frame Del (DEL) | VAF 40/122 reads (33%) | called by pindel, varscan2*
- ST14 | c.2566del p.*856Rfs*76 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- AGAP2 | c.1005C>A p.G335= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV57727116, COSV99222411; called by muse, mutect2, varscan2
- AGAP2 | c.369C>A p.L123= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99222190; called by muse, mutect2
- CALCOCO1 | c.66G>T p.R22= | Silent (SNP) | VAF 39/215 reads (18%) | catalogued as COSV100017188; called by muse, mutect2, varscan2
- DGKI | c.2394A>T p.S798= | Silent (SNP) | VAF 105/312 reads (34%) | catalogued as COSV99932837; called by muse, mutect2, varscan2
- HMCN1 | c.11940G>A p.V3980= | Silent (SNP) | VAF 60/365 reads (16%) | catalogued as COSV99625266; called by muse, mutect2, varscan2
- MSX1 | c.216G>A p.K72= | Silent (SNP) | VAF 266/939 reads (28%) | catalogued as COSV101235651; called by muse, mutect2, varscan2
- NEURL1 | c.36C>T p.P12= | Silent (SNP) | VAF 82/248 reads (33%) | catalogued as COSV100873094; called by muse, mutect2, varscan2
- NUTM2A | c.2346T>G p.P782= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV101095663; called by muse, mutect2, varscan2
- PLEKHA5 | c.2481A>G p.K827= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV100163676; called by muse, mutect2, varscan2
- PRR12 | c.2961C>T p.N987= (on ENST00000615927; = p.N1808= on NM_020719.3) | Silent (SNP) | VAF 78/290 reads (27%) | catalogued as rs563050549, COSV101330593; called by muse, mutect2, varscan2
- PRR5 | c.1023C>T p.P341= (on ENST00000336985 / NM_181333.4; = p.P332= on NM_015366.4) | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as rs771538941, COSV99134113; called by muse, mutect2, varscan2
- PTPRN2 | c.852C>G p.A284= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV101233861; called by muse, mutect2, varscan2
- RASGRF1 | c.2319C>T p.A773= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as rs147952942, COSV101174226; called by muse, mutect2, varscan2
- RFX4 | c.903C>T p.L301= (on ENST00000392842 / NM_213594.3; = p.L207= on NM_032491.6) | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as rs1565989576, COSV99985478; called by muse, mutect2, varscan2
- RIMS1 | c.3745C>A p.R1249= | Silent (SNP) | VAF 43/181 reads (24%) | catalogued as COSV53457473, COSV53485838; called by muse, mutect2, varscan2
- RNF112 | c.441C>A p.G147= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as COSV71978980; called by muse, mutect2, varscan2
- SLC19A2 | c.57C>A p.L19= | Silent (SNP) | VAF 51/139 reads (37%) | catalogued as COSV99356829; called by muse, mutect2, varscan2
- SRPK2 | c.1746T>C p.Y582= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV100623802; called by muse, mutect2, varscan2
- SUMO2 | c.126A>G p.K42= | Silent (SNP) | VAF 114/505 reads (23%) | catalogued as COSV100091999; called by muse, mutect2, varscan2
- SUN1 | c.186A>C p.A62= (on ENST00000405266 / NM_001367651.1; = p.A12= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100568569; called by muse, mutect2, varscan2
- SYNGAP1 | c.858G>T p.L286= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV99537968; called by muse, mutect2, varscan2
- TMEM63C | c.57G>T p.V19= | Silent (SNP) | VAF 42/83 reads (51%) | catalogued as COSV100029252; called by muse, mutect2, varscan2
- TTN | c.34265-5079G>A | Intron (SNP) | VAF 46/95 reads (48%) | catalogued as rs913650930, COSV59929921; called by muse, mutect2, varscan2
